Somatic mutation profile of tumor specimen TARGET-10-PATEAK-09A (aliquot TARGET-10-PATEAK-09A-01D) from TARGET case TARGET-10-PATEAK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,551 days).
Specimen TARGET-10-PATEAK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53700788-413f-41cf-b2ff-2df10014be8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATEAK-10A (Blood Derived Normal), aliquot TARGET-10-PATEAK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20cd23ba-932b-40dc-8507-78be49b5189d

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Intron 2, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2066G>A p.R689Q (on ENST00000281708 / NM_001349798.2; = p.R609Q on NM_018315.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55900091; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.2615G>A p.R872K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV51568851; called by muse, mutect2
- ELANE | c.639C>A p.H213Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.587); catalogued as rs199532353, COSV99708788; called by muse, mutect2
- FBXW7 | c.2065C>G p.R689G (on ENST00000281708 / NM_001349798.2; = p.R609G on NM_018315.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- FNIP2 | c.3259G>A p.V1087I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs771278684, COSV52438543; called by muse, mutect2, varscan2
- LDHA | c.957T>A p.S319R | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV57042791; called by muse, mutect2, varscan2
- MLLT1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as rs1224267190, COSV53133540; called by muse, mutect2, varscan2
- MYO15A | c.9310G>A p.G3104R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs781537466, COSV52767088; called by muse, mutect2, varscan2
- NOTCH1 | c.7595G>T p.W2532L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53098154; called by muse, mutect2, varscan2
- NXPH2 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55645249; called by muse, mutect2, varscan2
- SLCO1B3 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767676951, COSV53945505, COSV53946868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPHKAP | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200812632, COSV60871952; called by mutect2, varscan2
- TENM2 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.537); catalogued as rs1270296389, COSV72855041, COSV72862555; called by muse, mutect2, varscan2
- ADAMTS4 | c.2254G>T p.V752L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.009); called by muse, mutect2
- CRIM1 | c.2424C>A p.C808* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- FCRL5 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- LDHA | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- LPCAT2 | c.1415T>C p.F472S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, varscan2
- PCNX3 | c.6077C>A p.A2026D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- PIK3R1 | c.1345_1346del p.L449Tfs*2 (on ENST00000521381 / NM_181523.3; = p.L179Tfs*2 on NM_181504.4) | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel*
- TRNAU1AP | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZCCHC18 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2
- ZNF185 | c.1559C>A p.P520H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2
- ZNF521 | c.3665G>T p.G1222V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- ARID1A | c.5268A>G p.P1756= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- CRB1 | c.1677C>A p.S559= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV66328908; called by muse, mutect2, varscan2
- GCC1 | c.180G>T p.S60= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- KLRB1 | c.387G>T p.L129= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- MUC4 | c.5529C>T p.V1843= | Silent (SNP) | VAF 19/477 reads (4%) | catalogued as rs1456877922; called by muse, mutect2
- OR52N1 | c.153C>A p.I51= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs768454072; called by muse, varscan2
- OTOG | c.7752C>T p.S2584= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- PRKAB1 | c.81C>T p.G27= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, varscan2
- ZNF469 | c.5964C>A p.A1988= (on ENST00000437464; = p.A2016= on NM_001367624.2) | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- C1orf220 | n.91-200G>A | Intron (SNP) | VAF 13/62 reads (21%) | catalogued as rs1179159275; called by muse, mutect2, varscan2
- SPACA7 | c.94+2224G>A | Intron (SNP) | VAF 54/139 reads (39%) | catalogued as rs1342457073; called by muse, mutect2
- TRAJ50 | chr14:22492850 ins GCATTAAC | 3'Flank (INS) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
